Somatic mutation profile of tumor specimen 0DP8O9 from CCDI case PBCDIY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningeal melanocytoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 16.3 years (5,958 days).
Specimen 0DP8O9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 459cbc69-27be-44e6-8921-10f1487f59fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP8O2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddfbb995-bb84-4bc8-b3f8-d08820bcde35

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 221/700 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- GAGE12H | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 442/1144 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- TRAF3IP1 | c.361A>G p.S121G | Missense Mutation (SNP) | VAF 420/1046 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMPH | c.858C>T p.P286= | Silent (SNP) | VAF 191/1769 reads (11%) | catalogued as rs372756485, COSV57753118; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 28/826 reads (3%) | called by muse, mutect2
- TEX29 | c.138C>T p.Y46= | Silent (SNP) | VAF 238/957 reads (25%) | catalogued as rs143813497; called by muse, mutect2, varscan2
- VEZF1 | c.687C>G p.T229= | Silent (SNP) | VAF 45/1160 reads (4%) | called by muse, mutect2
- COLEC11 | c.-26-728A>G | Intron (SNP) | VAF 15/433 reads (3%) | called by muse, mutect2
- TIMM13 | c.*1080G>A | 3'UTR (SNP) | VAF 48/126 reads (38%) | called by mutect2, varscan2
